Somatic mutation profile of tumor specimen TCGA-D6-6823-01A (aliquot TCGA-D6-6823-01A-11D-1912-08) from TCGA case TCGA-D6-6823, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 51.0 years (18,611 days).
Specimen TCGA-D6-6823-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e61ec5c1-b61a-4041-b4bf-d312c1628b58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-6823-10A (Blood Derived Normal), aliquot TCGA-D6-6823-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2402dee-54cf-47d9-b110-4aea46a65280

The open-access MAF lists 112 somatic variants for this specimen: 90 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 18, Splice Site 4, Frame Shift Ins 4, Frame Shift Del 3, Intron 2, Nonsense Mutation 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSL3 | c.81T>A p.H27Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100657890; called by muse, mutect2, varscan2
- ACTR6 | c.557A>T p.E186V | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99498526; called by muse, mutect2, varscan2
- ADAMTS10 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99546588; called by muse, mutect2, varscan2
- ADGRG6 | c.1492C>G p.Q498E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99746249; called by muse, mutect2
- AXDND1 | c.1513A>C p.K505Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV100858280; called by muse, mutect2
- BMT2 | c.935A>G p.H312R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51778701, COSV51779109; called by muse, mutect2, varscan2
- BRCA1 | c.301+2T>G p.X101_splice | Splice Site (SNP) | VAF 31/85 reads (36%) | catalogued as COSV100523483; called by muse, mutect2, varscan2
- C3 | c.2729T>C p.V910A | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55575404; called by muse, mutect2, varscan2
- CDH16 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV100233727; called by muse, mutect2, varscan2
- CDH26 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); catalogued as COSV99721996; called by muse, mutect2, varscan2
- CDH3 | c.2414A>G p.D805G | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99867788; called by muse, mutect2, varscan2
- CDH8 | c.2243G>T p.G748V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV100180102; called by muse, mutect2, varscan2
- CENPS-CORT | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100471605, COSV58364693; called by muse, mutect2, varscan2
- CTNNA2 | c.1673T>C p.M558T | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760685287, COSV100559647; called by muse, mutect2, varscan2
- DGKD | c.838G>T p.E280* (on ENST00000264057 / NM_152879.3; = p.E236* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99895705; called by muse, mutect2, varscan2
- DHX58 | c.1505T>G p.L502R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99288081; called by muse, mutect2, varscan2
- DISC1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV54401601, COSV54409727, COSV99697366; called by muse, mutect2, varscan2
- EHF | c.407A>T p.E136V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV99140884; called by muse, mutect2, varscan2
- FAT3 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99963239; called by muse, mutect2, varscan2
- FBLN1 | c.1479C>G p.I493M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99410201; called by muse, mutect2, varscan2
- FBN1 | c.2782A>C p.N928H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100354198, COSV57334332; called by muse, mutect2, varscan2
- FKBP4 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99133605; called by muse, mutect2, varscan2
- FOXP1 | c.1428G>C p.Q476H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV100561277, COSV59534995; called by muse, varscan2
- FRMD3 | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as COSV100170734; called by muse, mutect2, varscan2
- FXR2 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV51468613; called by muse, mutect2, varscan2
- GALNT8 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99362584; called by muse, mutect2, varscan2
- GCG | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV100972740; called by muse, mutect2, varscan2
- GPAT3 | c.1007A>T p.Q336L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV100022832; called by muse, mutect2, varscan2
- INPPL1 | c.518+1G>A p.X173_splice | Splice Site (SNP) | VAF 22/71 reads (31%) | catalogued as COSV53353939; called by muse, mutect2, varscan2
- ITGB3 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101457555; called by muse, varscan2
- JAKMIP2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99507659; called by muse, mutect2, varscan2
- JRKL | c.1409T>G p.L470R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.693); catalogued as COSV99567134; called by muse, mutect2, varscan2
- KCNA1 | c.613A>T p.I205F | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV101230160; called by muse, mutect2, varscan2
- KCNB2 | c.2314G>C p.E772Q | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.166); catalogued as COSV101578694, COSV73048952; called by muse, mutect2, varscan2
- KIAA0232 | c.2801A>G p.Y934C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100300510; called by muse, mutect2, varscan2
- KRT4 | c.1346+2T>C p.X449_splice | Splice Site (SNP) | VAF 33/94 reads (35%) | catalogued as rs944841753, COSV99542734; called by muse, mutect2, varscan2
- KRTAP13-1 | c.186G>T p.E62D | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV62663787; called by muse, mutect2, varscan2
- LCP1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs755322384, COSV59940540; called by muse, mutect2, varscan2
- LDLRAD4 | c.201A>C p.Q67H | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100762028; called by muse, mutect2, varscan2
- LIFR | c.1898T>C p.I633T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs768471216, COSV99663572; called by muse, mutect2, varscan2
- LPAR3 | c.195del p.Y66Tfs*7 | Frame Shift Del (DEL) | VAF 47/143 reads (33%) | catalogued as COSV65453678; called by mutect2, pindel, varscan2
- LRFN1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs748854735, COSV50507825; called by muse, varscan2
- LRP2 | c.1750G>T p.V584L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV99787080; called by muse, mutect2, varscan2
- LRRFIP1 | c.1804T>G p.L602V (on ENST00000392000 / NM_001137552.2; = p.L578V on NM_004735.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99790510; called by muse, varscan2
- MBOAT7 | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99824662; called by muse, mutect2, varscan2
- MRPS35 | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99317342; called by muse, varscan2
- MUC4 | c.13151C>T p.T4384I (on ENST00000463781 / NM_018406.7; = p.T148I on NM_004532.6) | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.086); catalogued as COSV100204014; called by muse, mutect2, varscan2
- NAV2 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.834); catalogued as rs1292653194, COSV100585086; called by muse, mutect2, varscan2
- NDNF | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.231); catalogued as rs759106878, COSV101113108; called by muse, mutect2, varscan2
- NTRK3 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as rs764882745, COSV100445984, COSV100446285; called by muse, mutect2, varscan2
- OR11H12 | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 38/497 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs372134904, COSV101612528; called by muse, mutect2
- OR51A4 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1442441116, COSV100985214; called by muse, mutect2
- OR52M1 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100798557, COSV64172590, COSV64173152; called by muse, mutect2, varscan2
- OR8J1 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV100274898; called by muse, mutect2, varscan2
- OXA1L | c.1172C>A p.S391Y (on ENST00000285848; = p.S331Y on NM_005015.5) | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV99591062; called by muse, mutect2, varscan2
- PCDHB5 | c.2198G>C p.G733A | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV99167718; called by muse, mutect2, varscan2
- PFKFB2 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 51/178 reads (29%) | PolyPhen benign (0.237); catalogued as COSV65547108; called by muse, mutect2, varscan2
- PLK4 | c.2332A>G p.I778V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99584499; called by muse, mutect2, varscan2
- PLPPR4 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs756382926, COSV64566022, COSV64567848; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.435G>T p.W145C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100544094; called by muse, mutect2, varscan2
- PRDM15 | c.131+1G>T p.X44_splice | Splice Site (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99519544; called by muse, mutect2, varscan2
- RASGEF1A | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100988647; called by muse, mutect2, varscan2
- RBM6 | c.1903A>T p.T635S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99804825; called by muse, mutect2, varscan2
- RGS2 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773290344, COSV99343296; called by muse, mutect2, varscan2
- RP1 | c.3433T>C p.F1145L | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99606654; called by muse, mutect2
- SEMA3E | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100317709; called by muse, mutect2, varscan2
- SIM1 | c.2172C>A p.S724R | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV53491317, COSV99492093; called by muse, mutect2, varscan2
- SLC36A4 | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100419286; called by muse, mutect2, varscan2
- SLC39A3 | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99514129; called by muse, mutect2, varscan2
- SPI1 | c.159C>G p.F53L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99908732; called by muse, mutect2
- SYNE1 | c.4172G>A p.S1391N (on ENST00000367255 / NM_182961.4; = p.S1398N on NM_033071.3) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54994447; called by muse, mutect2, varscan2
- SYNJ2 | c.3937C>T p.P1313S | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100840075; called by muse, mutect2, varscan2
- TAS1R2 | c.2099C>T p.T700M | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.329); catalogued as rs149445409; called by muse, mutect2, varscan2
- TMC1 | c.375del p.K125Nfs*3 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs745767539, COSV52773318; called by pindel, varscan2
- TNIP3 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs1223646952, COSV99284362; called by muse, mutect2, varscan2
- TP53 | c.410T>A p.L137Q | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52661767, COSV53253629, COSV53721634; called by muse, mutect2, varscan2
- TRHR | c.824T>G p.F275C | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100304717; called by muse, mutect2
- TSBP1 | c.56T>G p.I19S | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100898732; called by muse, mutect2, varscan2
- TTYH2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs375427011; called by muse, mutect2, varscan2
- UBTF | c.2126C>T p.S709F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100255815; called by muse, mutect2, varscan2
- UNC5C | c.490T>A p.Y164N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV101497809; called by muse, mutect2, varscan2
- ZNF556 | c.944A>G p.Y315C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs201270528, COSV100298613; called by muse, mutect2, varscan2
- ZNF816 | c.577C>G p.Q193E | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as COSV54412238, COSV99554491; called by muse, mutect2, varscan2
- AP5M1 | c.273dup p.E92Rfs*12 | Frame Shift Ins (INS) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- CBWD6 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CSMD3 | c.1762C>A p.Q588K (on ENST00000297405 / NM_001363185.1; = p.Q484K on NM_052900.3) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); called by muse, mutect2
- FOS | c.522_529dup p.S177Lfs*14 | Frame Shift Ins (INS) | VAF 21/98 reads (21%) | called by mutect2, varscan2
- JAG2 | c.2366del p.N789Ifs*77 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- MZF1 | c.1848dup p.R617Efs*13 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- SCARF2 | c.1637_1641dup p.S548Gfs*50 | Frame Shift Ins (INS) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- ARPC2 | c.264A>G p.E88= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99826605; called by muse, mutect2, varscan2
- CCR8 | c.903T>G p.A301= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100413034; called by muse, mutect2, varscan2
- CETN1 | c.354C>T p.T118= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV59121931; called by muse, mutect2, varscan2
- CHERP | c.1233C>T p.H411= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs200951226, COSV52228701; called by muse, mutect2, varscan2
- FAM98B | c.870G>A p.R290= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV101131439; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1998G>A p.S666= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs760743255, COSV56273644; called by muse, mutect2, varscan2
- KCNK2 | c.1194C>T p.P398= (on ENST00000444842 / NM_001017425.3; = p.P383= on NM_014217.4) | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV101221936, COSV67206369; called by muse, mutect2, varscan2
- MKS1 | c.738A>G p.K246= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV100439489; called by muse, mutect2, varscan2
- NME9 | c.222C>T p.L74= (on ENST00000333911 / NM_001349024.2; = p.L52= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/92 reads (58%) | catalogued as COSV100444609; called by muse, mutect2, varscan2
- PHF3 | c.4956T>A p.P1652= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100013023; called by muse, mutect2, varscan2
- ROBO4 | c.2727C>A p.A909= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100127366; called by muse, mutect2, varscan2
- ROPN1L | c.150G>A p.S50= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs781546950, COSV56873316; called by muse, mutect2, varscan2
- SF3B2 | c.1233C>T p.D411= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100488319; called by muse, mutect2, varscan2
- TFIP11 | c.486C>T p.Y162= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs757131973, COSV68020650; called by muse, mutect2, varscan2
- USP35 | c.2928C>A p.I976= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs1411332169, COSV100416364; called by muse, mutect2, varscan2
- ZNF546 | c.1581T>C p.C527= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100713376; called by muse, mutect2, varscan2
- ZNF567 | c.633A>G p.G211= (on ENST00000536254 / NM_001322913.1; = p.G180= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs759591239, COSV62444483; called by muse, mutect2, varscan2
- ZNF572 | c.1470C>T p.H490= | Silent (SNP) | VAF 18/221 reads (8%) | catalogued as rs759111285, COSV100073870; called by muse, mutect2
- GCNT2 | c.926-34828C>T | Intron (SNP) | VAF 49/155 reads (32%) | catalogued as rs1328011318, COSV99399122; called by muse, mutect2, varscan2
- HERC2P3 | n.1282A>C | RNA (SNP) | VAF 7/40 reads (18%) | called by mutect2, varscan2
- PKD1L2 | n.1230T>A | RNA (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- RBMS1 | c.901-925A>G | Intron (SNP) | VAF 52/180 reads (29%) | catalogued as COSV100816750; called by muse, mutect2, varscan2
